Somatic mutation profile of tumor specimen C3L-00800-01 (aliquot CPT0025290009) from CPTAC case C3L-00800, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 41.8 years (15,279 days).
Specimen C3L-00800-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e25dc42-7eab-40fe-874f-d29b4fd64331.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00800-31 (Blood Derived Normal), aliquot CPT0029460002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dae92664-6836-4959-94de-ab806a91a6c5

The open-access MAF lists 44 somatic variants for this specimen: 34 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 4, Intron 3, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, 5'Flank 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.163dup p.E55Gfs*77 | Frame Shift Ins (INS) | VAF 46/175 reads (26%) | catalogued as rs869025615, CI071468; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCG2 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs142634180, COSV99419898; called by muse, mutect2, varscan2
- CA12 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.392); catalogued as COSV99458582; called by muse, mutect2, varscan2
- CYP4F11 | c.1173G>T p.L391F | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1313895231; called by muse, mutect2, varscan2
- DDAH1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV52306784; called by muse, mutect2
- FRMPD2 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as rs115907611, COSV59719953; called by muse, mutect2, varscan2
- FXR1 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 34/539 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV99976053; called by muse, mutect2
- IGHG4 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 126/865 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1192211502; called by muse, mutect2, varscan2
- KSR2 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772270920, COSV60382735; called by muse, mutect2
- MAGEL2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58568763; called by muse, varscan2
- NELL2 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.248); catalogued as rs145137395; called by muse, mutect2, varscan2
- PCDH7 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.976); catalogued as rs868551664, COSV100688422; called by muse, mutect2
- ABI3 | c.435C>G p.C145W | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ATP2A1 | c.1490A>G p.Y497C | Missense Mutation (SNP) | VAF 119/721 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COL9A3 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CPEB2 | c.1760G>A p.R587K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYP4F11 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAM83C | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM4 | c.746G>A p.C249Y | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- GRM6 | c.2047A>G p.K683E | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- HS3ST4 | c.735-1G>T p.X245_splice | Splice Site (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- ILF3 | c.197A>C p.D66A | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- LIMD2 | c.249C>G p.H83Q | Missense Mutation (SNP) | VAF 9/261 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); called by muse, mutect2
- PCDHA3 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 93/530 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDGFRA | c.925G>C p.V309L | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PKD1 | c.12428T>G p.L4143R (on ENST00000262304 / NM_001009944.3; = p.L4142R on NM_000296.4) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- SCIN | c.1855T>A p.C619S (on ENST00000297029 / NM_001112706.3; = p.C372S on NM_033128.3) | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC3A1 | c.335del p.P112Qfs*4 | Frame Shift Del (DEL) | VAF 110/551 reads (20%) | called by mutect2, pindel, varscan2
- SLC41A1 | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 28/650 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SOAT1 | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.092); called by muse, mutect2
- SYDE1 | c.1623del p.F542Sfs*7 | Frame Shift Del (DEL) | VAF 43/223 reads (19%) | called by mutect2, pindel, varscan2
- TIGIT | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 13/340 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2
- TRIML1 | c.1316A>T p.E439V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- VMA21 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 121/241 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MARK4 | c.1560T>C p.A520= | Silent (SNP) | VAF 28/266 reads (11%) | called by muse, mutect2, varscan2
- PTGER3 | c.1146G>A p.L382= | Silent (SNP) | VAF 44/180 reads (24%) | called by muse, mutect2, varscan2
- SMTNL2 | c.183C>T p.A61= | Silent (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- SYNDIG1L | c.207G>A p.R69= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2
- CHTF18 | chr16:788312 C>T | 5'Flank (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- DMAP1 | c.393+127A>G | Intron (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- INO80 | c.3049-2206C>T | Intron (SNP) | VAF 41/215 reads (19%) | called by muse, mutect2, varscan2
- KCTD17 | c.412-30G>A | Intron (SNP) | VAF 26/346 reads (8%) | catalogued as rs988785744; called by muse, mutect2
- PTPN20CP | n.661C>G | RNA (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- ST6GALNAC2 | chr17:76561121 T>C | 3'Flank (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
